Somatic mutation profile of tumor specimen TCGA-27-1834-01A (aliquot TCGA-27-1834-01A-01D-1494-08) from TCGA case TCGA-27-1834, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.3 years (20,568 days).
Specimen TCGA-27-1834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c14f036c-0125-4941-a743-5582621c1fe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1834-10A (Blood Derived Normal), aliquot TCGA-27-1834-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e568cb0-e725-4d4b-9e11-e2c4aabe6ebe

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS4B | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs754271798, COSV61139377; called by muse, mutect2, varscan2
- C9orf116 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 119/161 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65646517; called by muse, mutect2, varscan2
- CARF | c.1861T>C p.C621R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV57548065; called by muse, mutect2, varscan2
- CELSR3 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771709882, COSV50884054; called by muse, mutect2, varscan2
- CHD9 | c.5921C>T p.A1974V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs201408451, COSV54611731; called by muse, mutect2, varscan2
- COL6A2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56007715; called by muse, mutect2, varscan2
- CRNN | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 169/493 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55122429; called by muse, mutect2, varscan2
- CYP11B2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59995910, COSV59996388; called by muse, mutect2, varscan2
- DDR1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762082578, COSV61321876; called by muse, mutect2, varscan2
- DENND2C | c.1904C>T p.A635V (on ENST00000393274 / NM_001256404.2; = p.A578V on NM_198459.4) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67922158; called by muse, mutect2, varscan2
- DNAH17 | c.4034C>T p.T1345M | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs199839203, COSV67758391; called by muse, mutect2, varscan2
- DVL1 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV59563861; called by muse, mutect2, varscan2
- ENPEP | c.2525C>T p.T842M | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs200338472, COSV54451167; called by muse, mutect2, varscan2
- EPHA4 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 131/350 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as rs748076314, COSV56035910; called by muse, mutect2, varscan2
- FAM107B | c.139C>G p.P47A (on ENST00000378458 / NM_001320737.1; = p.P222A on NM_031453.3) | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51686511, COSV51693713; called by muse, mutect2, varscan2
- FLG | c.10538C>T p.A3513V | Missense Mutation (SNP) | VAF 179/496 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs143278829, COSV64243057; called by muse, mutect2, varscan2
- FZD10 | c.374A>T p.N125I | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV57474109; called by muse, mutect2, varscan2
- GPD2 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV60093463; called by muse, mutect2, varscan2
- GTF3C4 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60136619; called by muse, mutect2, varscan2
- HR | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.142); catalogued as COSV57192820; called by muse, mutect2, varscan2
- IFNB1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 294/404 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV66525132, COSV66525281; called by muse, varscan2
- LHCGR | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54298394; called by muse, mutect2, varscan2
- MBNL1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56830230, COSV56833536; called by muse, mutect2, varscan2
- MBNL1 | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56830257; called by muse, mutect2
- MVK | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV57332135; called by muse, mutect2, varscan2
- MYH15 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56312155; called by muse, mutect2
- NELL1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs371025282; called by muse, mutect2, varscan2
- NR3C2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV60992886; called by muse, mutect2, varscan2
- OPCML | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.145); catalogued as COSV59429281; called by muse, mutect2
- OR1J4 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 167/235 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV61589937; called by muse, mutect2, varscan2
- OR5M8 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59117130; called by muse, mutect2, varscan2
- OR6B1 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1465345184, COSV68770270; called by muse, mutect2, varscan2
- PHLDB2 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1209433982, COSV67312460; called by muse, mutect2, varscan2
- PTEN | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM090487, COSV64298260, COSV64301956; called by muse, mutect2, varscan2
- SEZ6 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV57981102; called by muse, mutect2, varscan2
- TSGA10 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV61823669; called by muse, mutect2
- ZNF839 | c.170C>T p.P57L (on ENST00000558850 / NM_001267827.1; = p.P173L on NM_018335.5) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV51757837; called by muse, mutect2, varscan2
- CNTN5 | c.842_851dup p.T285* | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- SRPRA | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- CCDC87 | c.651C>T p.F217= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as rs17853294, COSV59578208; called by muse, mutect2, varscan2
- CLCN1 | c.2265G>A p.P755= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs761474906, COSV58368300; called by muse, mutect2
- CSF2RA | c.357C>T p.T119= | Silent (SNP) | VAF 169/798 reads (21%) | catalogued as COSV100817887, COSV62625112; called by muse, mutect2, varscan2
- CSTF1 | c.1242G>A p.T414= | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as rs748667806, COSV53859070; called by muse, mutect2, varscan2
- EPHB1 | c.2166G>T p.V722= | Silent (SNP) | VAF 18/558 reads (3%) | catalogued as COSV67663261; called by muse, mutect2
- FOXA1 | c.1320C>T p.G440= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs752035534, COSV51646667; called by muse, mutect2, varscan2
- FRAS1 | c.8235G>A p.G2745= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs1194341277, COSV53618543; called by muse, mutect2, varscan2
- GNAT3 | c.207C>T p.F69= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV68069039; called by mutect2, varscan2
- MS4A4A | c.678C>T p.H226= | Silent (SNP) | VAF 74/197 reads (38%) | catalogued as COSV59701659; called by muse, mutect2, varscan2
- OLFM4 | c.1182T>A p.V394= | Silent (SNP) | VAF 166/263 reads (63%) | catalogued as COSV54578127; called by muse, mutect2, varscan2
- OR10G2 | c.294G>A p.P98= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs749275776, COSV73390396; called by muse, mutect2, varscan2
- PPM1D | c.324C>T p.G108= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV59956235; called by muse, mutect2
- RPL32 | c.30C>T p.P10= | Silent (SNP) | VAF 60/531 reads (11%) | catalogued as rs144517633; called by muse, mutect2, varscan2
- SOX30 | c.594C>T p.G198= | Silent (SNP) | VAF 89/199 reads (45%) | catalogued as COSV53937931; called by muse, mutect2, varscan2
- TRRAP | c.6201C>T p.A2067= (on ENST00000359863 / NM_001244580.1; = p.A2049= on NM_003496.3) | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV62846429; called by muse, mutect2
- XIRP2 | c.618C>T p.D206= (on ENST00000628543; = p.D381= on NM_152381.6) | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as COSV54680205, COSV54708203; called by muse, mutect2, varscan2
- DST | c.4297-4120T>C | Intron (SNP) | VAF 40/357 reads (11%) | catalogued as COSV99753196; called by muse, mutect2, varscan2
